Surgical pathology report (de-identified scan), TCGA case TCGA-44-7672, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-7672-01A (Primary Tumor).

[page 1 of 2]
DEPARTMENT OF PATHOLOGY AND LABORATORY MEDICINE

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Left upper lobe
- B. Lymph node level 5
- C. Lymph node level 11
- D. 9L fat pad
- E. Lymph node level 8
- F. Lymph node level 7

CLINICAL NOTES

CLINICAL HISTORY: Cavitory left upper lobe lung lesion.

FROZEN SECTION DIAGNOSIS

Lung, left [REDACTED] ectomy: Non-small cell carcinoma; negative margins. [REDACTED]

GROSS DESCRIPTION

A. Received unfixed for frozen section and tissue procurement, labeled upper lobe, is a 16 x 12 x 1.5 cm left upper lobectomy specimen. There is a 2.5 x 2.0 x 1.5 cm mass lesion which pleural puckering present on the posterior surface, adjacent to the bronchus. It has an irregular border and a gray-white cut surface with incorporated anthracotic pigment. No additional mass lesions are identified. A representative section of tumor is submitted for frozen section diagnosis, as well as the bronchial and vascular margins. A portion of tumor is also submitted for tissue procurement as requested. Additional representative sections submitted in six blocks. RS-8. Summary of sections: AFS1 - margins; AFS2 - tumor; A1-A5 - tumor; A6 - uninvolved lung tissue.

B. Received fresh, labeled "lymph node level 5" are two rubbery tan gray-gold tissues measuring [REDACTED] and 0.9 cm. in greatest dimension which are submitted in toto. [REDACTED].

C. Received fresh, labeled "lymph node level 11" is a 1.2 x 0.8 x 0.3 cm. rubbery gray bl [REDACTED] issue which is trisected and entirely submitted in one block. [REDACTED].

D. Received fresh, labeled "9L fat pad" are two fragments of soft golden yellow adipose tissue measuring 0.6 cm. in greatest dimension and 1.4 x 0.7 x 0.3 cm. The largest tissue is [REDACTED] ected and the specimens are entirely submitted in one block. [REDACTED].

E. Received fresh, labeled "lymph node level 8" is a 0.8 cm. in greatest dimension gray rubbery [REDACTED] ue which is bisected and entirely submitted in one block. [REDACTED].

F. Received fresh, labeled "lymph node level 7" are two soft gray black tissues averaging [REDACTED] in greatest dimension which are submitted in toto. [REDACTED]

[page 2 of 2]
[REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma.
Histologic grade: Moderately-differentiated.
Primary tumor (pT): pT1b (2.5 cm in greatest dimension).
Margins of resection: Negative.
Direct extension of tumor: Negative.
Venous (large vessel) invasion: Negative.
Arterial (large vessel) invasion: Negative.
Lymphatic (small vessel) invasion: Not identified.
Regional lymph nodes: Five negative lymph nodes (0/5).
Comments: Carcinoma invades up toward the pleural surface, but does not appear to directly involve the visceral pleura.

[REDACTED]

DIAGNOSIS

- A. Lung, left upper lobe, lobectomy:
Adenocarcinoma, 2.5 cm in greatest dimension.

DIAGNOSIS

- Negative margins of excision.
Angiolymphatic invasion not identified.
- B. Lymph node, level 5, regional resection:
Two negative lymph nodes (0/2).
- C. Lymph node, level 11, biopsy:
One negative lymph node (0/1).
- D. Soft tissue, "9L fat pad, biopsy:
Benign fibroadipose tissue and one negative lymph node (0/1).
- E. Lymph node, level 8, biopsy:
One negative lymph node (0/1).
- F. Lymph node, level 7, biopsy:
Lymphoid tissue and fibrous connective tissue; no definite lymph node identified; no malignancy identified.
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 296cad4a-6d2a-4737-a46b-54333f4ea1e6 (TCGA-44-7672.65857640-A645-4830-897C-3DEAFB4AC36F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).